Somatic mutation profile of tumor specimen TCGA-A3-A8OU-01A (aliquot TCGA-A3-A8OU-01A-11D-A36X-10) from TCGA case TCGA-A3-A8OU, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 75.0 years (27,377 days).
Specimen TCGA-A3-A8OU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20f918bd-0716-4866-ba08-a1f37c310a2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A8OU-10A (Blood Derived Normal), aliquot TCGA-A3-A8OU-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2bc0948-94e6-483e-82e3-710cceb9ccfb

The open-access MAF lists 82 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7216G>A p.V2406M | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1557739557, COSV63873643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.3811C>T p.P1271S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100314894; called by muse, mutect2
- AOC3 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100395877; called by muse, mutect2, varscan2
- B4GALT1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122940; called by muse, mutect2, varscan2
- BTN2A1 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs1042075476, COSV100438324; called by muse, mutect2, varscan2
- CADPS2 | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57371526; called by muse, mutect2, varscan2
- CEMIP | c.2369A>T p.Q790L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99585775; called by muse, mutect2, varscan2
- CENPF | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100871387; called by muse, mutect2, varscan2
- COIL | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99537886; called by muse, mutect2, varscan2
- CORIN | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004818049, COSV99902601; called by muse, mutect2
- CPSF2 | c.731T>A p.L244* | Nonsense Mutation (SNP) | VAF 66/310 reads (21%) | catalogued as COSV100102383; called by muse, mutect2, varscan2
- DAPK1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.342); catalogued as rs745756807, COSV100800663; called by muse, mutect2, varscan2
- DLG2 | c.268T>A p.C90S (on ENST00000650630 / NM_001351274.2; = p.C53S on NM_001142699.3) | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as COSV101069813; called by muse, mutect2, varscan2
- ELAC1 | c.20T>A p.F7Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99494703; called by muse, mutect2, varscan2
- EMC4 | c.319T>C p.W107R | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs1436936254, COSV99970777; called by muse, mutect2, varscan2
- EPC2 | c.2335A>G p.I779V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.768); catalogued as rs1191065623, COSV99308856; called by muse, mutect2, varscan2
- ERBIN | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52314824; called by muse, mutect2, varscan2
- ERICH1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs756470228, COSV100032102; called by muse, mutect2, varscan2
- FCGR2C | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 64/238 reads (27%) | catalogued as COSV100912407; called by muse, mutect2, varscan2
- FERMT1 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99450843; called by muse, mutect2, varscan2
- FMO5 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV99566462; called by muse, mutect2
- FRS2 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100165625; called by muse, mutect2
- GAB3 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100850380; called by muse, mutect2, varscan2
- GABRB3 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV100157570; called by muse, mutect2, varscan2
- HNRNPL | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs375903656; called by muse, mutect2, varscan2
- HTT | c.6025G>A p.D2009N | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs773337081, COSV100750230; called by muse, varscan2
- KIAA1549 | c.5164A>G p.S1722G | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs1003295687, COSV99649337; called by muse, mutect2, varscan2
- KLHDC8B | c.708C>G p.H236Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV100234023; called by mutect2, varscan2
- LARP1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.025); catalogued as COSV100303269; called by muse, mutect2
- LIAS | c.423A>T p.L141F (on ENST00000261434 / NM_001363700.2; = p.L244F on NM_006859.4) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99787477; called by muse, mutect2, varscan2
- MAML3 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100504853; called by muse, mutect2, varscan2
- MAP7D1 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100294193; called by muse, mutect2, varscan2
- OR5K2 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV101415939; called by muse, mutect2, varscan2
- PBRM1 | c.2242del p.D748Mfs*27 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as COSV56277344; called by mutect2, pindel, varscan2
- PCCB | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as CM983749, COSV99290981; called by muse, mutect2, varscan2
- PDCD6IP | c.638T>G p.I213R | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100218415; called by muse, mutect2
- PER2 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs370526340; called by muse, mutect2, varscan2
- PGM1 | c.849T>A p.F283L | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100936423; called by muse, mutect2, varscan2
- POTEE | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.307); catalogued as COSV100386417; called by muse, mutect2
- PRDM5 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99309539; called by muse, mutect2, varscan2
- PSMB10 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99344352; called by muse, mutect2, varscan2
- RBM12B | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV101234448; called by muse, mutect2, varscan2
- SCN3A | c.3904T>A p.S1302T | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99325289; called by muse, mutect2, varscan2
- SDAD1 | c.1729A>C p.K577Q | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV100668516; called by muse, mutect2, varscan2
- SGO2 | c.2108A>G p.Q703R | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV100764569; called by muse, mutect2, varscan2
- SLC26A2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1418899122, COSV99639908; called by muse, mutect2, varscan2
- STXBP5L | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99871379; called by muse, mutect2, varscan2
- TAF2 | c.3041T>C p.V1014A | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100978316; called by muse, mutect2, varscan2
- TRIP10 | c.1361T>C p.I454T (on ENST00000313244 / NM_001288962.2; = p.I398T on NM_004240.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs544311636, COSV99837719; called by muse, mutect2, varscan2
- TRO | c.2035A>G p.N679D | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99435470; called by muse, mutect2
- TTN | c.84598C>A p.L28200M (on ENST00000591111; = p.L20776M on NM_003319.4) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60399951; called by muse, mutect2
- TTN | c.63008C>T p.P21003L (on ENST00000591111; = p.P13579L on NM_003319.4) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV100588465; called by muse, mutect2, varscan2
- TXNDC11 | c.991T>C p.F331L (on ENST00000356957 / NM_001303447.2; = p.F304L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99297145; called by muse, mutect2, varscan2
- ZAN | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.537); catalogued as COSV100768932; called by muse, mutect2
- ZC3H13 | c.4607T>G p.L1536W (on ENST00000242848 / NM_001330565.2; = p.L1537W on NM_015070.6) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99667234; called by muse, mutect2, varscan2
- ZGPAT | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs1420686179, COSV100203030; called by muse, mutect2, varscan2
- ANK3 | c.3942dup p.V1315Cfs*8 (on ENST00000280772 / NM_001320874.2; = p.V449Cfs*8 on NM_001149.3) | Frame Shift Ins (INS) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- HMCN1 | c.16798dup p.A5600Gfs*20 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- MICAL3 | c.2997_3017del p.Y1001_E1007del | In Frame Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, varscan2
- NEK5 | c.549_551del p.N183del | In Frame Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel, varscan2
- SIDT1 | c.579del p.D196Tfs*45 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ZC3H18 | c.2788del p.E930Sfs*3 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- BSCL2 | c.822C>T p.I274= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99627758; called by muse, mutect2, varscan2
- BTC | c.144C>T p.D48= | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV101201459; called by muse, mutect2, varscan2
- CDH20 | c.921A>T p.A307= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV99403892; called by muse, mutect2, varscan2
- CORIN | c.1711C>T p.L571= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV99902600; called by muse, mutect2
- DAG1 | c.2499C>T p.N833= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100444595; called by muse, mutect2, varscan2
- DGKE | c.781C>T p.L261= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV99400613; called by muse, mutect2, varscan2
- EPO | c.480C>T p.I160= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99402488; called by muse, mutect2, varscan2
- IGLJ4 | c.15A>G p.G5= | Silent (SNP) | VAF 49/158 reads (31%) | called by muse, mutect2, varscan2
- NDST2 | c.1413C>A p.G471= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100013520; called by muse, mutect2
- TMCO6 | c.1170G>A p.L390= | Silent (SNP) | VAF 61/235 reads (26%) | catalogued as COSV99346919; called by muse, mutect2, varscan2
- TRIM75P | c.363G>A p.Q121= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2949C>T p.S983= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV99550264; called by muse, mutect2, varscan2
- TTLL11 | c.696C>G p.A232= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1421228048, COSV100388284; called by muse, mutect2, varscan2
- UBR4 | c.5184G>C p.V1728= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100919872; called by muse, mutect2, varscan2
- WDR55 | c.420T>A p.V140= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100845524; called by muse, mutect2
- ZFAND2B | c.501C>A p.T167= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV99202353; called by muse, mutect2, varscan2
- ZFR2 | c.1674G>A p.A558= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs371139874, COSV99506837; called by muse, mutect2
- PFKL | c.86-1315G>A | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100826917; called by muse, mutect2, varscan2
- RAB37 | chr17:74737059 A>G | 5'Flank (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100462429; called by muse, mutect2, varscan2
